Gene-level copy-number profile of tumor specimen ALCH-B2BH-TTP1-B from ALCHEMIST case ALCH-B2BH, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 64.8 years (23,683 days).
Specimen ALCH-B2BH-TTP1-B: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1d02c198-90ac-4158-9622-607829599eed.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2BH-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/0c8f627b-d38a-478a-b252-b35afa8c1e04

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 66; copy number 1: 18,344; copy number 2: 39,328; copy number 3: 968; copy number 4: 131; copy number 5: 74; copy number 12: 3.

Homozygous deletions (total copy number 0; autosomes only): 63 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:33,145,399–33,182,059, 2 genes: TRIM62, AL662907.2.
- chr1:222,468,094–222,519,732, 4 genes: CICP13, AL513314.2, RNU6-791P, AL592148.2.
- chr2:232,456,125–232,487,834, 2 genes: ALPI, ECEL1.
- chr8:141,353,403–141,367,286, 2 genes: AC100803.3, GPR20.
- chr8:141,434,545–141,437,954, 1 gene (within-gene range 0–2): AC100803.4.
- chr9:19,108,375–19,201,046, 2 genes: PLIN2, AL161909.1.
- chr9:96,313,444–96,418,370, 4 genes: SLC35D2, ZNF367, NSA2P7, AL133477.1.
- chr9:104,927,553–104,928,892, 1 gene (within-gene range 0–1): AL359182.1.
- chr9:124,853,417–125,417,586, 18 genes: WDR38, RPL35, ARPC5L, GOLGA1, RNU4-82P, SCAI, FXNP2, PPP6C, PRPS1P2, RPSAP76, RABEPK, HSPA5, AL354710.2, GAPVD1, AL354710.1, RNU6-1020P, AL627223.1, Metazoa_SRP.
- chr10:103,446,786–103,462,695, 4 genes: CALHM2, AL139339.2, AL139339.1, CALHM1.
- chr16:15,094,411–15,154,564, 6 genes (within-gene range 0–2): AC139256.1, NPIPP1, PKD1P6-NPIPP1, PKD1P6, MIR6511B2, Y_RNA.
- chr18:59,778,572–59,930,330, 4 genes: GLUD1P4, AC098847.1, PMAIP1, AC107990.1.
- chr19:2,427,638–2,456,959, 2 genes (within-gene range 0–1): LMNB2, MIR7108.
- chr19:17,292,131–17,342,731, 6 genes: ABHD8, MRPL34, AC010463.3, DDA1, ANO8, GTPBP3.
- chr19:34,481,758–34,512,304, 1 gene: WTIP.
- chr19:35,030,470–35,113,664, 4 genes (within-gene range 0–1): SCN1B, HPN, HPN-AS1, AC020907.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:80,351,132–81,165,266, 22 genes, copy number 5: AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1.
- chr20:62,386,303–63,240,495, 52 genes, copy number 5: AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1, AL117379.1, GID8, SLC17A9, BHLHE23, LINC01749, LINC00029, LINC01056, HAR1B, AL096828.4, HAR1A, AL096828.2, AL096828.1, MIR124-3, YTHDF1, AL096828.3, BIRC7, MIR3196.
- chr20:64,290,187–64,327,972, 3 genes, copy number 12: CICP4, LINC00266-1, AL137028.1.

Autosomal genes at a single copy (total copy number 1): 15,492. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
